Gene-level copy-number profile of tumor specimen ALCH-B01Z-TTR1-A from ALCHEMIST case ALCH-B01Z, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.9 years (23,709 days).
Specimen ALCH-B01Z-TTR1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6993046a-aef4-4420-b766-37f3e296081f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B01Z-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/64a5422d-f571-4482-b080-1927a0520f9e

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 17; copy number 2: 909; copy number 3: 338; copy number 4: 23,588; copy number 5: 1,021; copy number 6: 22,834; copy number 7: 1,272; copy number 8: 8,821; copy number 9: 50; copy number 12: 9; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:42,183,659–42,569,353, 12 genes: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1.
- chr22:25,279,529–25,339,975, 4 genes: AL022332.1, AL022324.4, IGLL3P, AL022324.1.
- chr22:25,351,418–25,405,377, 1 gene: LRP5L.
- chr22:25,436,312–25,437,823, 2 genes: AL008721.1, IGLVIVOR22-1.
- chr22:25,476,218–25,479,971, 1 gene (within-gene range 0–1): AL008721.2.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:25,434,324–25,435,070, 1 gene, copy number 14: AL022324.3.

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
